Somatic mutation profile of tumor specimen ALCH-B37F-TTP1-A (aliquot ALCH-B37F-TTP1-A-1-0-D-A799-36) from ALCHEMIST case ALCH-B37F, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 62.9 years (22,971 days).
Specimen ALCH-B37F-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5337e374-0a34-4a06-9cb9-95275685247d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B37F-NB1-A (Blood Derived Normal), aliquot ALCH-B37F-NB1-A-1-0-D-A799-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5dbcdaa7-d65c-4b01-9856-074326b112b1

The open-access MAF lists 422 somatic variants for this specimen: 266 protein-altering or splice-affecting, 81 silent, 75 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 224, Silent 81, Intron 32, Nonsense Mutation 16, RNA 13, 3'UTR 12, Frame Shift Del 9, 5'Flank 7, Splice Site 6, 3'Flank 6, Frame Shift Ins 5, 5'UTR 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA1 | c.4463dup p.N1488Kfs*2 | Frame Shift Ins (INS) | VAF 53/197 reads (27%) | catalogued as rs80357620; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- AAR2 | c.904C>G p.L302V | Missense Mutation (SNP) | VAF 117/612 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV57925093; called by muse, mutect2, varscan2
- ABCC8 | c.4324G>C p.E1442Q | Missense Mutation (SNP) | VAF 67/203 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as rs759663539; called by muse, mutect2, varscan2
- ABCG8 | c.692C>A p.P231Q | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55392360, COSV99700350; called by muse, mutect2, varscan2
- ACP6 | c.223G>C p.E75Q | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.251); catalogued as rs782298170; called by muse, mutect2, varscan2
- AFAP1L1 | c.1556C>T p.A519V | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as rs1413854340, COSV57044407, COSV57044996; called by muse, mutect2, varscan2
- ALB | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 67/217 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as rs1332629192; called by muse, mutect2, varscan2
- AP3B2 | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 86/272 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1233321722; called by muse, mutect2, varscan2
- ARHGEF17 | c.4672G>T p.G1558W | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773017083, COSV55234632; called by muse, mutect2, varscan2
- ASAP3 | c.1123C>G p.Q375E | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.117); catalogued as rs747227838; called by muse, mutect2, varscan2
- ATP10A | c.2512G>T p.E838* | Nonsense Mutation (SNP) | VAF 22/138 reads (16%) | catalogued as COSV63519907; called by muse, mutect2, varscan2
- ATP8A2 | c.1802G>T p.R601I | Missense Mutation (SNP) | VAF 44/162 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54958723; called by muse, mutect2, varscan2
- ATRNL1 | c.2113T>A p.Y705N | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as COSV61806197; called by muse, mutect2, varscan2
- C2orf16 | c.1447G>T p.D483Y | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as COSV68645545, COSV68645863; called by muse, mutect2, varscan2
- CAMK1D | c.1112G>A p.R371K | Missense Mutation (SNP) | VAF 63/151 reads (42%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.267); catalogued as COSV66610237, COSV66611619; called by muse, mutect2, varscan2
- CAMSAP1 | c.2059G>C p.G687R | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.014); catalogued as COSV56725839; called by muse, mutect2
- CASR | c.866C>A p.T289K | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.607); catalogued as rs755840531; called by muse, mutect2, varscan2
- CBX8 | c.928G>A p.G310S | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.9); PolyPhen benign (0.001); catalogued as rs769620160; called by muse, mutect2, varscan2
- CDK5RAP2 | c.5192T>C p.I1731T | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs1469517516; called by muse, mutect2, varscan2
- CEPT1 | c.503G>T p.G168V | Missense Mutation (SNP) | VAF 48/273 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64112204; called by muse, mutect2, varscan2
- CFHR5 | c.836A>T p.Y279F | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.261); catalogued as COSV99054581; called by muse, mutect2, varscan2
- CNTN6 | c.2166+1G>T p.X722_splice | Splice Site (SNP) | VAF 14/39 reads (36%) | catalogued as COSV63184499, COSV63193415; called by muse, mutect2, varscan2
- COBLL1 | c.3064G>A p.A1022T (on ENST00000392717; = p.A984T on NM_014900.5) | Missense Mutation (SNP) | VAF 48/231 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1182663305; called by muse, mutect2, varscan2
- CSMD3 | c.10777C>G p.Q3593E (on ENST00000297405 / NM_001363185.1; = p.Q3424E on NM_052900.3) | Missense Mutation (SNP) | VAF 77/263 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as COSV99840741; called by muse, mutect2, varscan2
- CSPG4 | c.4860C>A p.Y1620* | Nonsense Mutation (SNP) | VAF 27/81 reads (33%) | catalogued as rs1218986746; called by muse, mutect2, varscan2
- CYP7B1 | c.816G>T p.E272D | Missense Mutation (SNP) | VAF 12/169 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.059); catalogued as COSV59585726; called by muse, mutect2
- DAXX | c.1111C>T p.R371W | Missense Mutation (SNP) | VAF 47/255 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1186523174, COSV56467177; called by muse, mutect2, varscan2
- DGKK | c.487C>G p.P163A | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.007); catalogued as COSV101052858; called by muse, mutect2, varscan2
- DSCAM | c.4750del p.E1584Kfs*4 | Frame Shift Del (DEL) | VAF 50/146 reads (34%) | catalogued as COSV68021636; called by mutect2, pindel, varscan2
- EFNA5 | c.328G>A p.G110R | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100320907; called by muse, mutect2, varscan2
- EMILIN3 | c.1429C>G p.L477V | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.425); catalogued as COSV100182635; called by muse, mutect2, varscan2
- FAM90A10P | c.263G>T p.R88L | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.011); catalogued as rs1237413250; called by mutect2, varscan2
- FHL3 | c.721G>A p.D241N | Missense Mutation (SNP) | VAF 32/226 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.795); catalogued as COSV65952408; called by muse, mutect2, varscan2
- FSHR | c.1747C>T p.L583F | Missense Mutation (SNP) | VAF 54/171 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as rs769427769; called by muse, mutect2, varscan2
- GLI2 | c.1709C>T p.T570M (on ENST00000361492 / NM_001374353.1; = p.T587M on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 66/423 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs202040905; called by muse, mutect2, varscan2
- IFI27L1 | c.4G>T p.G2* | Nonsense Mutation (SNP) | VAF 18/106 reads (17%) | catalogued as rs1465624444; called by muse, mutect2, varscan2
- IGDCC4 | c.2776C>T p.R926C | Missense Mutation (SNP) | VAF 108/279 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.049); catalogued as rs202153933; called by muse, mutect2, varscan2
- IGLV3-27 | c.122G>T p.C41F | Missense Mutation (SNP) | VAF 215/422 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.404); catalogued as rs761748083; called by muse, mutect2, varscan2
- INSC | c.1677G>T p.L559F | Missense Mutation (SNP) | VAF 58/170 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65413946; called by muse, mutect2, varscan2
- INSC | c.1678G>T p.V560F | Missense Mutation (SNP) | VAF 59/171 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV65409053; called by muse, mutect2, varscan2
- JPH3 | c.1151C>T p.A384V | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as rs538190270; called by mutect2, varscan2
- KCNH3 | c.2327G>A p.R776Q | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.885); catalogued as rs776972210; called by muse, mutect2, varscan2
- KCNV2 | c.1409G>T p.G470V | Missense Mutation (SNP) | VAF 46/185 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM163514; called by muse, mutect2, varscan2
- KDM5A | c.3697C>T p.L1233F | Missense Mutation (SNP) | VAF 132/372 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66995709; called by muse, mutect2, varscan2
- LRRFIP1 | c.1387G>C p.E463Q (on ENST00000392000 / NM_001137552.2; = p.E439Q on NM_004735.4) | Missense Mutation (SNP) | VAF 40/137 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.037); catalogued as rs752502135; called by muse, mutect2, varscan2
- MAGI2 | c.3308G>C p.G1103A | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.049); catalogued as COSV62643841, COSV62699106; called by muse, mutect2, varscan2
- MARF1 | c.4799G>C p.G1600A | Missense Mutation (SNP) | VAF 30/235 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs774217553; called by muse, mutect2, varscan2
- MTMR12 | c.1925G>A p.R642H | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.999); catalogued as rs754133953, COSV53784261; called by muse, mutect2, varscan2
- MYBPH | c.810del p.S271Afs*146 | Frame Shift Del (DEL) | VAF 12/48 reads (25%) | catalogued as rs1240262634; called by mutect2, pindel, varscan2
- MYO15A | c.1763G>T p.R588L | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.139); catalogued as COSV52757921; called by muse, mutect2, varscan2
- NAT9 | c.202A>G p.I68V | Missense Mutation (SNP) | VAF 12/256 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1204273158; called by muse, mutect2
- NCR2 | c.715C>G p.Q239E | Missense Mutation (SNP) | VAF 53/223 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.045); catalogued as COSV66100497; called by muse, mutect2, varscan2
- NPAT | c.1606del p.Q536Kfs*5 | Frame Shift Del (DEL) | VAF 13/116 reads (11%) | catalogued as COSV53722111; called by mutect2, pindel, varscan2
- NRSN1 | c.554G>C p.R185T | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as COSV101027211, COSV104429082; called by muse, mutect2, varscan2
- NXPE3 | c.1532G>C p.R511T | Missense Mutation (SNP) | VAF 52/269 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV56292283; called by muse, mutect2, varscan2
- ONECUT3 | c.458del p.P153Rfs*12 | Frame Shift Del (DEL) | VAF 4/20 reads (20%) | catalogued as rs1314898307; called by pindel, varscan2
- OR10P1 | c.406C>T p.L136F | Missense Mutation (SNP) | VAF 53/119 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs566208675; called by muse, mutect2, varscan2
- OR13C5 | c.939A>T p.R313S | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV66164162, COSV66165405; called by muse, mutect2, varscan2
- OR2B11 | c.613G>C p.V205L | Missense Mutation (SNP) | VAF 53/191 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.049); catalogued as COSV59511691; called by muse, varscan2
- OR4D5 | c.538G>T p.D180Y | Missense Mutation (SNP) | VAF 43/258 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV58309638; called by muse, mutect2, varscan2
- OR4Q3 | c.876C>A p.N292K | Missense Mutation (SNP) | VAF 25/281 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.22); catalogued as COSV59179129; called by muse, mutect2
- OR51F2 | c.382A>G p.I128V | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.463); catalogued as rs753796848; called by muse, mutect2, varscan2
- OR5D13 | c.204G>T p.L68F | Missense Mutation (SNP) | VAF 37/121 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100687094; called by muse, mutect2, varscan2
- PACS2 | c.1567G>A p.D523N | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV57650652; called by muse, mutect2, varscan2
- PAX4 | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 84/345 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770923465, COSV58388673; called by muse, mutect2, varscan2
- PDZRN4 | c.152G>T p.R51L | Missense Mutation (SNP) | VAF 79/232 reads (34%) | SIFT tolerated, low confidence (0.22); catalogued as rs184000271; called by muse, mutect2, varscan2
- PEG3 | c.1805G>C p.R602P | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV55627174; called by muse, mutect2, varscan2
- PHF20L1 | c.2645C>G p.S882* | Nonsense Mutation (SNP) | VAF 25/242 reads (10%) | catalogued as COSV55194368; called by muse, mutect2, varscan2
- PKP1 | c.1899G>C p.G633= | Splice Region (SNP) | VAF 14/52 reads (27%) | catalogued as COSV99825785; called by muse, mutect2, varscan2
- PLEKHH2 | c.4409C>A p.P1470H | Missense Mutation (SNP) | VAF 59/324 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs202229114; called by muse, mutect2, varscan2
- PLEKHN1 | c.1405G>C p.E469Q (on ENST00000379409; = p.E417Q on NM_032129.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.636); catalogued as rs764672947, COSV100379206; called by muse, mutect2, varscan2
- POTEH | c.107G>C p.R36T | Missense Mutation (SNP) | VAF 238/560 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.109); catalogued as COSV58887486; called by muse, varscan2
- PPP1R3C | c.892A>G p.S298G | Missense Mutation (SNP) | VAF 72/192 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs766858533; called by muse, mutect2, varscan2
- PRR14L | c.1096G>T p.G366C | Missense Mutation (SNP) | VAF 21/159 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.106); catalogued as COSV57885707; called by muse, mutect2, varscan2
- PTCH2 | c.370G>C p.E124Q | Missense Mutation (SNP) | VAF 29/230 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.066); catalogued as COSV64711128; called by muse, mutect2, varscan2
- PTEN | c.380G>C p.G127A | Missense Mutation (SNP) | VAF 92/238 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64289089, COSV64294277; called by muse, mutect2, varscan2
- PTEN | c.811T>G p.F271V | Missense Mutation (SNP) | VAF 42/127 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.927); catalogued as COSV64291328; called by muse, mutect2, varscan2
- RAD51AP2 | c.710C>G p.S237C | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.847); catalogued as COSV101208301; called by muse, mutect2, varscan2
- RALGAPB | c.3076C>T p.R1026W | Missense Mutation (SNP) | VAF 47/315 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs749916417, COSV53442154; called by muse, mutect2, varscan2
- RRP12 | c.2872G>A p.V958M | Missense Mutation (SNP) | VAF 32/185 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs370226569; called by muse, mutect2, varscan2
- RYR3 | c.5077A>G p.T1693A | Missense Mutation (SNP) | VAF 38/143 reads (27%) | SIFT tolerated (0.89); PolyPhen benign (0.005); catalogued as COSV66804300; called by muse, mutect2, varscan2
- SEL1L | c.253del p.E85Kfs*10 | Frame Shift Del (DEL) | VAF 17/65 reads (26%) | catalogued as COSV60918804; called by mutect2, pindel, varscan2
- SLC16A6 | c.1246G>C p.E416Q | Missense Mutation (SNP) | VAF 43/170 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0.124); catalogued as COSV100517267; called by muse, mutect2, varscan2
- SLC35F4 | c.310G>A p.E104K (on ENST00000339762 / NM_001352015.2; = p.E68K on NM_001206920.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 65/406 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.06); catalogued as rs376265188; called by muse, mutect2, varscan2
- SLC5A8 | c.1460C>A p.T487K | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as rs750721928, COSV73311155; called by muse, mutect2, varscan2
- SP140 | c.1883T>G p.F628C | Missense Mutation (SNP) | VAF 29/229 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1181538802; called by muse, mutect2, varscan2
- SPEG | c.827A>C p.Q276P | Missense Mutation (SNP) | VAF 33/144 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs755439723; called by muse, mutect2, varscan2
- SRRM2 | c.31C>T p.R11W | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV57068426; called by muse, mutect2, varscan2
- TEX29 | c.254G>A p.S85N | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.279); catalogued as rs1191503701, COSV52095490; called by muse, mutect2
- TMEM202 | c.388C>G p.L130V | Missense Mutation (SNP) | VAF 24/153 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.802); catalogued as COSV58982919; called by muse, mutect2, varscan2
- TRUB1 | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.14); catalogued as rs936112765; called by muse, mutect2, varscan2
- TTN | c.24116G>T p.R8039L (on ENST00000591111; = p.R7112L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/61 reads (30%) | PolyPhen probably damaging (0.986); catalogued as rs376290076, COSV100624013; called by muse, mutect2, varscan2
- VGLL4 | c.665A>G p.K222R | Missense Mutation (SNP) | VAF 82/204 reads (40%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.786); catalogued as rs757493212; called by muse, varscan2
- WDR19 | c.801G>C p.E267D | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs776714032; called by muse, mutect2, varscan2
- ZAN | c.3227G>A p.C1076Y | Missense Mutation (SNP) | VAF 66/246 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1012578936; called by muse, mutect2, varscan2
- ZFYVE26 | c.4712C>G p.P1571R | Missense Mutation (SNP) | VAF 93/493 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.465); catalogued as rs1224729069; called by muse, mutect2, varscan2
- ZNF135 | c.586A>T p.R196W (on ENST00000313434 / NM_001289401.2; = p.R208W on NM_003436.4) | Missense Mutation (SNP) | VAF 102/313 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.408); catalogued as COSV57883809; called by muse, mutect2, varscan2
- ZNF219 | c.353G>T p.R118L | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); catalogued as COSV53881890; called by muse, mutect2, varscan2
- ZNF536 | c.2053C>T p.R685C | Missense Mutation (SNP) | VAF 59/178 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1389441917; called by muse, mutect2, varscan2
- ABCC8 | c.3162+5G>T | Splice Region (SNP) | VAF 45/150 reads (30%) | called by muse, mutect2, varscan2
- ABHD6 | c.941G>T p.R314M | Missense Mutation (SNP) | VAF 64/171 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- ABL2 | c.870G>A p.M290I (on ENST00000502732 / NM_007314.4; = p.M275I on NM_005158.5) | Missense Mutation (SNP) | VAF 74/273 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- ADAMTSL3 | c.2141C>A p.P714H | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- ADGRL3 | c.4426G>T p.E1476* (on ENST00000506720 / NM_001322402.2; = p.E1365* on NM_015236.6) | Nonsense Mutation (SNP) | VAF 119/416 reads (29%) | called by muse, mutect2, varscan2
- AIFM3 | c.1149G>A p.M383I | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- AKNA | c.184G>T p.A62S | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- ALCAM | c.931T>A p.Y311N | Missense Mutation (SNP) | VAF 120/459 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ALG1 | c.237G>T p.Q79H | Missense Mutation (SNP) | VAF 143/687 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ANKRD12 | c.3440C>T p.T1147I | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- ANKRD36 | c.995C>G p.S332C | Missense Mutation (SNP) | VAF 20/184 reads (11%) | SIFT tolerated, low confidence (0.16); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ANKRD36 | c.2026C>A p.L676I | Missense Mutation (SNP) | VAF 82/339 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- ARHGAP1 | c.77C>A p.A26D | Missense Mutation (SNP) | VAF 18/244 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.179); called by muse, mutect2
- ARL13A | c.428T>C p.I143T | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- ARSK | c.440G>C p.R147T | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.56); called by muse, mutect2, varscan2
- ATP8B3 | c.1832T>A p.L611Q | Missense Mutation (SNP) | VAF 63/248 reads (25%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- BNIP5 | c.827C>T p.P276L | Missense Mutation (SNP) | VAF 43/243 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- C15orf39 | c.2781C>G p.D927E | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- C9orf153 | c.62G>A p.C21Y | Missense Mutation (SNP) | VAF 48/168 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.32); called by muse, mutect2, varscan2
- CABIN1 | c.1155G>C p.E385D | Missense Mutation (SNP) | VAF 29/273 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CACNA1D | c.1625C>T p.S542F (on ENST00000350061 / NM_001128840.3; = p.S562F on NM_000720.4) | Missense Mutation (SNP) | VAF 47/158 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- CACNA1G | c.3481A>G p.R1161G | Missense Mutation (SNP) | VAF 62/240 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- CACNA1I | c.1414C>G p.P472A | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- CACNA1S | c.1726C>A p.L576M | Missense Mutation (SNP) | VAF 54/400 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CATIP | c.822G>C p.L274F | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.494); called by muse, mutect2, varscan2
- CCDC27 | c.1901T>G p.V634G | Missense Mutation (SNP) | VAF 101/506 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- CD248 | c.785T>C p.F262S | Missense Mutation (SNP) | VAF 56/219 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- CDYL2 | c.423del p.S142Vfs*5 | Frame Shift Del (DEL) | VAF 27/149 reads (18%) | called by mutect2, pindel, varscan2
- CEPT1 | c.502G>T p.G168* | Nonsense Mutation (SNP) | VAF 48/274 reads (18%) | called by muse, mutect2, varscan2
- CERS2 | c.681T>G p.N227K | Missense Mutation (SNP) | VAF 57/242 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- CKAP5 | c.2738A>T p.N913I | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CLCN2 | c.837C>G p.F279L | Missense Mutation (SNP) | VAF 75/345 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CLOCK | c.1159_1161del p.R387del | In Frame Del (DEL) | VAF 21/223 reads (9%) | called by pindel, varscan2
- CNOT4 | c.55G>C p.E19Q | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- COL24A1 | c.3079G>T p.A1027S | Missense Mutation (SNP) | VAF 56/220 reads (25%) | SIFT tolerated (0.53); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- COL28A1 | c.1069C>A p.P357T | Missense Mutation (SNP) | VAF 71/177 reads (40%) | SIFT tolerated (0.52); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- COL6A2 | c.1415G>A p.G472E | Missense Mutation (SNP) | VAF 113/316 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CPXM2 | c.265C>A p.P89T | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- CREBBP | c.7277T>C p.L2426P | Missense Mutation (SNP) | VAF 19/278 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.797); called by muse, mutect2
- CRY2 | c.1715A>G p.E572G | Missense Mutation (SNP) | VAF 34/201 reads (17%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- CSMD1 | c.1672T>G p.F558V (on ENST00000520002; = p.F557V on NM_033225.6) | Missense Mutation (SNP) | VAF 32/256 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- DDX24 | c.1524_1525insT p.T509Yfs*15 | Frame Shift Ins (INS) | VAF 94/448 reads (21%) | called by mutect2, pindel, varscan2
- DDX28 | c.133C>T p.Q45* | Nonsense Mutation (SNP) | VAF 41/252 reads (16%) | called by muse, mutect2, varscan2
- DDX42 | c.1157G>C p.R386P | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DGKK | c.1411+1G>T p.X471_splice | Splice Site (SNP) | VAF 41/117 reads (35%) | called by muse, mutect2, varscan2
- DHX29 | c.3178G>A p.E1060K | Missense Mutation (SNP) | VAF 57/341 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- DOCK1 | c.3687G>T p.E1229D | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated (0.64); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- DOP1A | c.917G>T p.S306I | Missense Mutation (SNP) | VAF 35/204 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DPP6 | c.21G>T p.R7S | Missense Mutation (SNP) | VAF 84/344 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- DUSP15 | c.255-12_264del p.X85_splice (on ENST00000278979 / NM_001320479.1; = p.X88_splice on NM_080611.4) | Splice Site (DEL) | VAF 14/62 reads (23%) | called by mutect2, pindel
- E2F8 | c.112G>C p.D38H | Missense Mutation (SNP) | VAF 37/274 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- EFNA3 | c.198C>A p.Y66* | Nonsense Mutation (SNP) | VAF 18/153 reads (12%) | called by muse, mutect2, varscan2
- EFNA5 | c.329G>T p.G110V | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- EGFLAM | c.1708G>C p.D570H | Missense Mutation (SNP) | VAF 40/233 reads (17%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- EPHA3 | c.2808G>T p.E936D | Missense Mutation (SNP) | VAF 29/135 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- ERBIN | c.244A>G p.T82A | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- FAIM2 | c.569A>G p.Y190C | Missense Mutation (SNP) | VAF 49/121 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- FBXO15 | c.1185A>T p.K395N | Missense Mutation (SNP) | VAF 18/149 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- FBXO16 | c.271A>T p.K91* | Nonsense Mutation (SNP) | VAF 55/506 reads (11%) | called by muse, mutect2, varscan2
- FEZF1 | c.557T>C p.L186P | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.829); called by muse, mutect2
- GPHN | c.1198A>T p.T400S (on ENST00000315266 / NM_001377519.1; = p.T433S on NM_020806.5) | Missense Mutation (SNP) | VAF 121/460 reads (26%) | SIFT tolerated (0.66); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- GTF2F1 | c.1502A>G p.N501S | Missense Mutation (SNP) | VAF 37/369 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- GTF3C1 | c.5923A>G p.R1975G | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- HEXB | c.640C>G p.L214V | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.381); called by muse, mutect2
- HKDC1 | c.1945G>A p.D649N | Missense Mutation (SNP) | VAF 91/271 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- HPS3 | c.379A>G p.I127V | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- ICA1L | c.58C>G p.Q20E | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- ICE1 | c.135C>G p.I45M | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- IFI27L1 | c.5G>T p.G2V | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- ITPR2 | c.4792G>C p.D1598H | Missense Mutation (SNP) | VAF 116/372 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- KANK4 | c.1277A>T p.E426V | Missense Mutation (SNP) | VAF 71/220 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- KBTBD7 | c.443C>G p.S148C | Missense Mutation (SNP) | VAF 129/375 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- KCNH1 | c.997C>G p.Q333E | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNJ15 | c.467T>C p.I156T | Missense Mutation (SNP) | VAF 49/149 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); called by muse, mutect2, varscan2
- KIAA0895 | c.292A>G p.K98E (on ENST00000297063 / NM_001100425.2; = p.K47E on NM_015314.3) | Missense Mutation (SNP) | VAF 26/266 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.777); called by muse, mutect2
- KLHL14 | c.1241G>C p.R414T | Missense Mutation (SNP) | VAF 23/148 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- KRTAP5-9 | c.133G>T p.V45L | Missense Mutation (SNP) | VAF 40/285 reads (14%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.302); called by muse, mutect2
- LRP2 | c.4993dup p.V1665Gfs*18 | Frame Shift Ins (INS) | VAF 36/249 reads (14%) | called by mutect2, pindel, varscan2
- LRRC7 | c.2598C>A p.H866Q (on ENST00000651989 / NM_001370785.2; = p.H833Q on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/190 reads (14%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- LRRC74B | c.343C>G p.R115G | Missense Mutation (SNP) | VAF 78/280 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LRRIQ3 | c.852dup p.A285Cfs*6 | Frame Shift Ins (INS) | VAF 8/28 reads (29%) | called by mutect2, pindel
- MALRD1 | c.5261G>A p.W1754* | Nonsense Mutation (SNP) | VAF 35/141 reads (25%) | called by muse, mutect2, varscan2
- MALRD1 | c.5262G>T p.W1754C | Missense Mutation (SNP) | VAF 35/141 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAP4K5 | c.488C>T p.A163V | Missense Mutation (SNP) | VAF 71/317 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MBD3L1 | c.136C>A p.P46T | Missense Mutation (SNP) | VAF 80/434 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- MCM2 | c.868C>G p.L290V | Missense Mutation (SNP) | VAF 30/173 reads (17%) | SIFT tolerated (0.63); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- MDGA2 | c.2203G>T p.D735Y (on ENST00000399232 / NM_001113498.2; = p.D437Y on NM_182830.4) | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- MICALL1 | c.1397_1411del p.I466_S470del | In Frame Del (DEL) | VAF 16/130 reads (12%) | called by mutect2, pindel
- MIDEAS | c.2800G>C p.E934Q | Missense Mutation (SNP) | VAF 17/293 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.968); called by muse, mutect2
- MMAB | c.603G>C p.Q201H | Missense Mutation (SNP) | VAF 85/285 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.473); called by muse, mutect2, varscan2
- MOG | c.14C>G p.S5* | Nonsense Mutation (SNP) | VAF 34/331 reads (10%) | called by muse, mutect2, varscan2
- MRPS15 | c.364A>T p.T122S | Missense Mutation (SNP) | VAF 20/236 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.285); called by muse, mutect2
- MUC4 | c.12943+2T>A p.X4315_splice (on ENST00000463781 / NM_018406.7; = p.X79_splice on NM_004532.6) | Splice Site (SNP) | VAF 8/50 reads (16%) | called by muse, mutect2, varscan2
- MYBPC3 | c.1315G>T p.G439C | Missense Mutation (SNP) | VAF 24/211 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- NAV1 | c.3721G>C p.E1241Q | Missense Mutation (SNP) | VAF 32/176 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- NCK1 | c.882G>T p.M294I | Missense Mutation (SNP) | VAF 69/119 reads (58%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NMUR1 | c.506C>A p.A169D | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- OR1G1 | c.434T>C p.V145A | Missense Mutation (SNP) | VAF 77/207 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- OR2A12 | c.207C>A p.D69E | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- OR2A2 | c.786_803del p.D262_E267del | In Frame Del (DEL) | VAF 38/343 reads (11%) | called by mutect2, pindel
- OR7G2 | c.706A>G p.I236V | Missense Mutation (SNP) | VAF 76/341 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.247); called by muse, varscan2
- OTOG | c.3780G>T p.L1260F | Missense Mutation (SNP) | VAF 51/126 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- PCDHA3 | c.2086G>T p.V696F | Missense Mutation (SNP) | VAF 26/157 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.482); called by muse, mutect2, varscan2
- PCDHB9 | c.245G>A p.G82E | Missense Mutation (SNP) | VAF 70/230 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCLO | c.1174G>T p.A392S | Missense Mutation (SNP) | VAF 99/345 reads (29%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PCM1 | c.1088A>G p.D363G | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); called by mutect2, varscan2
- PDE4D | c.1735A>T p.M579L (on ENST00000340635 / NM_001104631.2; = p.M443L on NM_006203.4) | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.467); called by muse, varscan2
- PLCD4 | c.2083G>C p.E695Q | Missense Mutation (SNP) | VAF 23/198 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- PLEKHD1 | c.650+1G>C p.X217_splice | Splice Site (SNP) | VAF 18/224 reads (8%) | called by muse, mutect2
- PLXNA4 | c.305A>T p.Q102L | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.806); called by muse, mutect2
- PLXNC1 | c.839C>A p.S280Y | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PPM1A | c.58_64del p.N20Cfs*5 | Frame Shift Del (DEL) | VAF 49/491 reads (10%) | called by mutect2, pindel
- PPP4R3C | c.772G>T p.E258* | Nonsense Mutation (SNP) | VAF 46/121 reads (38%) | called by muse, mutect2, varscan2
- PRUNE2 | c.5242G>T p.E1748* | Nonsense Mutation (SNP) | VAF 28/107 reads (26%) | called by muse, mutect2, varscan2
- PTPRF | c.1306C>A p.P436T | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- RASAL1 | c.1975G>C p.E659Q | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- RGPD2 | c.3839C>G p.S1280* | Nonsense Mutation (SNP) | VAF 14/57 reads (25%) | called by mutect2, varscan2
- SAMD7 | c.212-2A>T p.X71_splice | Splice Site (SNP) | VAF 26/180 reads (14%) | called by muse, mutect2, varscan2
- SAMD9L | c.3886G>C p.V1296L | Missense Mutation (SNP) | VAF 6/89 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.077); called by muse, mutect2
- SAP130 | c.280G>T p.E94* | Nonsense Mutation (SNP) | VAF 41/297 reads (14%) | called by muse, mutect2, varscan2
- SCN2A | c.4163C>G p.A1388G | Missense Mutation (SNP) | VAF 28/218 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- SCN7A | c.3285del p.R1095Sfs*8 | Frame Shift Del (DEL) | VAF 41/368 reads (11%) | called by mutect2, pindel, varscan2
- SDSL | c.772G>T p.V258L | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- SEC23IP | c.1398G>T p.E466D | Missense Mutation (SNP) | VAF 98/253 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.561); called by muse, mutect2, varscan2
- SIM1 | c.498C>G p.C166W | Missense Mutation (SNP) | VAF 82/224 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLAMF9 | c.14C>T p.P5L | Missense Mutation (SNP) | VAF 65/341 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC12A6 | c.1874_1884del p.L625Hfs*90 (on ENST00000354181 / NM_001365088.1; = p.L574Hfs*90 on NM_005135.2) | Frame Shift Del (DEL) | VAF 127/461 reads (28%) | called by mutect2, pindel, varscan2
- SLC39A5 | c.136C>G p.L46V | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- SLC4A7 | c.1454G>C p.G485A | Missense Mutation (SNP) | VAF 32/167 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SLCO5A1 | c.2534A>T p.E845V | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SLF2 | c.56G>T p.G19V | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- SMARCA5 | c.512C>G p.S171C | Missense Mutation (SNP) | VAF 43/92 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- SMARCD2 | c.292G>T p.G98C | Missense Mutation (SNP) | VAF 34/61 reads (56%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- SNAP25 | c.172G>C p.E58Q | Missense Mutation (SNP) | VAF 23/188 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- SND1 | c.2079C>A p.D693E | Missense Mutation (SNP) | VAF 25/247 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- SNRPN | c.136G>C p.D46H | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SQLE | c.1058C>G p.P353R | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SREBF2 | c.-13_19del | Translation Start Site (DEL) | VAF 36/190 reads (19%) | called by mutect2, pindel
- SRPRA | c.885C>G p.C295W | Missense Mutation (SNP) | VAF 39/197 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.244); called by muse, mutect2, varscan2
- SSC5D | c.392C>G p.S131* | Nonsense Mutation (SNP) | VAF 25/368 reads (7%) | called by muse, mutect2
- STRIP2 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- SUN3 | c.307A>G p.K103E | Missense Mutation (SNP) | VAF 16/217 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.097); called by muse, mutect2
- TAS1R1 | c.759T>A p.D253E | Missense Mutation (SNP) | VAF 57/216 reads (26%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- TBC1D23 | c.643C>G p.Q215E | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- TCEAL5 | c.494T>G p.M165R | Missense Mutation (SNP) | VAF 38/200 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- TEX15 | c.7222T>A p.C2408S (on ENST00000256246; = p.C2791S on NM_001350162.2) | Missense Mutation (SNP) | VAF 66/195 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- TMC5 | c.833G>T p.R278M | Missense Mutation (SNP) | VAF 26/155 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.36); called by muse, mutect2
- TMC5 | c.835A>T p.S279C | Missense Mutation (SNP) | VAF 26/158 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.43); called by muse, mutect2
- TMEM211 | c.71C>G p.P24R | Missense Mutation (SNP) | VAF 79/783 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TNFRSF8 | c.145C>A p.P49T | Missense Mutation (SNP) | VAF 140/310 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- TOGARAM2 | c.902T>C p.I301T | Missense Mutation (SNP) | VAF 29/202 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TP53 | c.258_267dup p.S90Tfs*62 | Frame Shift Ins (INS) | VAF 30/124 reads (24%) | called by mutect2, varscan2
- TRANK1 | c.5593C>G p.Q1865E | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- TRIOBP | c.3550C>T p.P1184S | Missense Mutation (SNP) | VAF 52/87 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- TTC39C | c.467T>G p.I156S (on ENST00000317571 / NM_001135993.2; = p.I95S on NM_153211.4) | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- TYK2 | c.1637C>G p.S546C | Missense Mutation (SNP) | VAF 77/294 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- VGLL4 | c.756C>G p.I252M | Missense Mutation (SNP) | VAF 174/422 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, varscan2
- VPS13C | c.604C>T p.H202Y (on ENST00000644861 / NM_020821.3; = p.H159Y on NM_017684.5) | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- WDR97 | c.2320G>T p.A774S | Missense Mutation (SNP) | VAF 39/244 reads (16%) | SIFT tolerated (0.62); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZMYM1 | c.72T>G p.I24M | Missense Mutation (SNP) | VAF 18/158 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ZNF30 | c.1343G>C p.R448T | Missense Mutation (SNP) | VAF 34/207 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.505); called by muse, mutect2, varscan2
- ZNF555 | c.736C>T p.H246Y | Missense Mutation (SNP) | VAF 120/465 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF581 | c.142C>A p.P48T | Missense Mutation (SNP) | VAF 30/328 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2
- ZNF721 | c.473G>A p.C158Y (on ENST00000338977; = p.C170Y on NM_133474.4) | Missense Mutation (SNP) | VAF 125/425 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- ZNF772 | c.649T>C p.S217P | Missense Mutation (SNP) | VAF 36/237 reads (15%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF92 | c.205G>C p.E69Q | Missense Mutation (SNP) | VAF 111/496 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- ZSCAN20 | c.2498A>G p.Q833R | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ABCA12 | c.877C>T p.L293= | Silent (SNP) | VAF 37/304 reads (12%) | called by muse, mutect2, varscan2
- ABCC5 | c.1344A>G p.K448= | Silent (SNP) | VAF 11/129 reads (9%) | called by muse, mutect2
- ABCC8 | c.4491G>A p.R1497= | Silent (SNP) | VAF 46/152 reads (30%) | catalogued as rs778997556, COSV56849720; called by muse, mutect2, varscan2
- ADAM29 | c.129C>G p.T43= | Silent (SNP) | VAF 18/49 reads (37%) | called by muse, mutect2, varscan2
- ADAMTS2 | c.1260G>A p.G420= | Silent (SNP) | VAF 64/182 reads (35%) | catalogued as rs376231597; called by muse, mutect2, varscan2
- ANK1 | c.1857T>C p.R619= | Silent (SNP) | VAF 86/274 reads (31%) | called by muse, mutect2, varscan2
- ARHGAP18 | c.1209G>A p.L403= | Silent (SNP) | VAF 186/406 reads (46%) | called by muse, mutect2, varscan2
- ARHGAP30 | c.2505C>T p.S835= | Silent (SNP) | VAF 37/230 reads (16%) | called by muse, mutect2, varscan2
- ARMH4 | c.1398T>G p.A466= | Silent (SNP) | VAF 20/193 reads (10%) | called by muse, mutect2
- C8orf34 | c.168C>A p.G56= | Silent (SNP) | VAF 7/47 reads (15%) | called by muse, mutect2, varscan2
- CACNG2 | c.765G>T p.V255= | Silent (SNP) | VAF 26/264 reads (10%) | catalogued as COSV100269117; called by muse, mutect2
- CBY2 | c.60C>A p.T20= | Silent (SNP) | VAF 56/246 reads (23%) | called by muse, mutect2, varscan2
- CCDC85C | c.324C>T p.F108= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as rs1259533224, COSV101208239; called by muse, mutect2, varscan2
- CCDC96 | c.1479C>A p.I493= | Silent (SNP) | VAF 10/71 reads (14%) | called by muse, mutect2, varscan2
- CECR2 | c.2145G>C p.G715= (on ENST00000342247 / NM_001290047.2; = p.G532= on NM_001290046.1) | Silent (SNP) | VAF 70/132 reads (53%) | called by muse, mutect2, varscan2
- CFAP44 | c.3951G>A p.L1317= | Silent (SNP) | VAF 20/149 reads (13%) | called by muse, mutect2, varscan2
- CHD6 | c.1548C>T p.A516= | Silent (SNP) | VAF 267/562 reads (48%) | called by muse, mutect2, varscan2
- CRACD | c.102C>G p.G34= | Silent (SNP) | VAF 15/102 reads (15%) | called by muse, mutect2, varscan2
- CYB5R3 | c.246G>A p.S82= | Silent (SNP) | VAF 36/158 reads (23%) | catalogued as rs572851751; called by muse, mutect2, varscan2
- CYP2F1 | c.1212G>A p.T404= | Silent (SNP) | VAF 15/174 reads (9%) | catalogued as rs541959207; called by muse, mutect2, varscan2
- DHX16 | c.2796C>T p.C932= | Silent (SNP) | VAF 18/128 reads (14%) | called by muse, mutect2, varscan2
- DOCK2 | c.2085T>A p.V695= | Silent (SNP) | VAF 93/267 reads (35%) | called by muse, mutect2, varscan2
- DPEP1 | c.987C>G p.L329= | Silent (SNP) | VAF 34/205 reads (17%) | called by muse, mutect2, varscan2
- DPP6 | c.27C>A p.T9= | Silent (SNP) | VAF 24/85 reads (28%) | catalogued as COSV101342043, COSV68064783; called by muse, mutect2, varscan2
- ECE1 | c.729C>G p.A243= | Silent (SNP) | VAF 206/489 reads (42%) | catalogued as rs763305486, COSV99941903; called by muse, mutect2, varscan2
- ENTHD1 | c.438G>T p.R146= | Silent (SNP) | VAF 6/86 reads (7%) | called by muse, mutect2
- EXD3 | c.1683G>A p.E561= | Silent (SNP) | VAF 17/88 reads (19%) | called by muse, mutect2, varscan2
- F10 | c.1017G>T p.A339= | Silent (SNP) | VAF 42/413 reads (10%) | catalogued as rs764999398, COSV65022078; called by muse, mutect2, varscan2
- FAM83E | c.1278G>C p.P426= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as rs758345361; called by muse, mutect2, varscan2
- FGFBP3 | c.285T>C p.H95= | Silent (SNP) | VAF 9/64 reads (14%) | catalogued as rs757710382; called by muse, mutect2, varscan2
- FREM2 | c.9150G>C p.R3050= | Silent (SNP) | VAF 151/430 reads (35%) | called by muse, mutect2, varscan2
- GFI1 | c.1125G>A p.K375= | Silent (SNP) | VAF 66/441 reads (15%) | called by muse, mutect2, varscan2
- GPR37 | c.330G>T p.P110= | Silent (SNP) | VAF 16/33 reads (48%) | called by muse, mutect2, varscan2
- GPRC6A | c.2193G>A p.E731= | Silent (SNP) | VAF 26/71 reads (37%) | catalogued as rs1256301828; called by muse, mutect2, varscan2
- GSTM4 | c.516C>T p.P172= | Silent (SNP) | VAF 62/447 reads (14%) | catalogued as rs1553233053; called by muse, mutect2, varscan2
- GUCY2D | c.2748T>A p.I916= | Silent (SNP) | VAF 79/223 reads (35%) | called by muse, mutect2, varscan2
- H2AC12 | c.69G>C p.G23= | Silent (SNP) | VAF 34/121 reads (28%) | catalogued as rs142132040, COSV63616721; called by muse, mutect2, varscan2
- HLA-DQB2 | c.210C>T p.S70= | Silent (SNP) | VAF 50/349 reads (14%) | catalogued as COSV68615273; called by muse, mutect2, varscan2
- HTR5A | c.852C>A p.A284= | Silent (SNP) | VAF 65/301 reads (22%) | catalogued as COSV99839950; called by muse, mutect2, varscan2
- ITPR2 | c.4083A>C p.S1361= | Silent (SNP) | VAF 60/153 reads (39%) | called by muse, mutect2, varscan2
- JHY | c.1143G>A p.T381= | Silent (SNP) | VAF 30/156 reads (19%) | catalogued as rs764612693, COSV57079807; called by muse, mutect2, varscan2
- KCNH2 | c.3198G>A p.L1066= | Silent (SNP) | VAF 7/39 reads (18%) | called by muse, mutect2, varscan2
- KIF1A | c.612C>A p.T204= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as COSV57498344; called by muse, mutect2, varscan2
- KLF1 | c.477C>A p.P159= | Silent (SNP) | VAF 16/48 reads (33%) | called by muse, mutect2, varscan2
- KRTAP5-9 | c.135G>T p.V45= | Silent (SNP) | VAF 41/291 reads (14%) | called by muse, mutect2
- LRRC38 | c.783G>C p.A261= | Silent (SNP) | VAF 194/431 reads (45%) | called by muse, mutect2, varscan2
- MELTF | c.684G>A p.K228= | Silent (SNP) | VAF 31/168 reads (18%) | called by muse, mutect2, varscan2
- MET | c.510C>T p.S170= | Silent (SNP) | VAF 113/270 reads (42%) | called by muse, mutect2, varscan2
- NMUR1 | c.507C>A p.A169= | Silent (SNP) | VAF 9/70 reads (13%) | called by muse, mutect2, varscan2
- NXPE3 | c.1533G>A p.R511= | Silent (SNP) | VAF 53/273 reads (19%) | called by muse, mutect2, varscan2
- OR11H6 | c.165G>A p.L55= | Silent (SNP) | VAF 63/209 reads (30%) | called by muse, mutect2, varscan2
- OR5K3 | c.201T>A p.V67= | Silent (SNP) | VAF 124/495 reads (25%) | called by muse, mutect2, varscan2
- OR7C2 | c.486C>A p.T162= | Silent (SNP) | VAF 106/356 reads (30%) | catalogued as COSV50180399; called by muse, mutect2, varscan2
- OR8D2 | c.429A>T p.I143= | Silent (SNP) | VAF 19/114 reads (17%) | catalogued as COSV62488425; called by muse, mutect2, varscan2
- OR8H3 | c.864C>A p.L288= | Silent (SNP) | VAF 13/88 reads (15%) | catalogued as COSV100539064, COSV57908442; called by muse, mutect2, varscan2
- OR8J3 | c.141C>A p.T47= | Silent (SNP) | VAF 32/252 reads (13%) | called by muse, mutect2, varscan2
- P2RY13 | c.177C>A p.I59= | Silent (SNP) | VAF 91/508 reads (18%) | called by muse, mutect2, varscan2
- PALB2 | c.1611G>A p.S537= | Silent (SNP) | VAF 34/250 reads (14%) | catalogued as rs730881874; ClinVar: likely benign / uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- PCDHGB4 | c.825C>T p.A275= | Silent (SNP) | VAF 64/169 reads (38%) | catalogued as rs370023698; called by muse, mutect2, varscan2
- PELI3 | c.960C>G p.A320= | Silent (SNP) | VAF 26/162 reads (16%) | called by muse, mutect2, varscan2
- PIK3C3 | c.2289A>T p.G763= | Silent (SNP) | VAF 24/226 reads (11%) | called by muse, mutect2
- PPIP5K2 | c.1512T>C p.S504= | Silent (SNP) | VAF 20/96 reads (21%) | catalogued as rs782067991; called by muse, mutect2, varscan2
- PRR35 | c.198C>G p.S66= | Silent (SNP) | VAF 13/86 reads (15%) | called by muse, mutect2, varscan2
- PSAT1 | c.1038T>C p.Y346= (on ENST00000376588 / NM_058179.4; = p.Y300= on NM_021154.5) | Silent (SNP) | VAF 144/402 reads (36%) | called by muse, mutect2, varscan2
- PSMA1 | c.594G>T p.T198= | Silent (SNP) | VAF 12/69 reads (17%) | catalogued as COSV67166090; called by muse, mutect2, varscan2
- RHOT2 | c.1680C>T p.A560= | Silent (SNP) | VAF 44/230 reads (19%) | catalogued as rs370698054; called by muse, mutect2, varscan2
- RUNDC3A | c.453C>A p.T151= | Silent (SNP) | VAF 29/75 reads (39%) | called by muse, mutect2, varscan2
- RYR3 | c.6687C>A p.G2229= | Silent (SNP) | VAF 36/98 reads (37%) | catalogued as rs752194470; called by muse, mutect2, varscan2
- SDK1 | c.2934G>C p.L978= | Silent (SNP) | VAF 44/119 reads (37%) | called by muse, mutect2, varscan2
- SENP7 | c.885C>G p.L295= | Silent (SNP) | VAF 28/207 reads (14%) | called by muse, mutect2, varscan2
- SEPHS2 | c.1032G>A p.L344= | Silent (SNP) | VAF 12/35 reads (34%) | called by muse, mutect2, varscan2
- SKAP1 | c.489G>C p.R163= | Silent (SNP) | VAF 51/208 reads (25%) | called by muse, mutect2, varscan2
- SLC9A2 | c.588A>G p.A196= | Silent (SNP) | VAF 32/187 reads (17%) | called by muse, mutect2, varscan2
- SMAP2 | c.594T>C p.I198= | Silent (SNP) | VAF 29/189 reads (15%) | called by muse, mutect2, varscan2
- SNTA1 | c.717C>T p.C239= | Silent (SNP) | VAF 112/247 reads (45%) | called by muse, mutect2, varscan2
- TTC14 | c.852A>G p.L284= | Silent (SNP) | VAF 6/52 reads (12%) | called by muse, mutect2
- VPS52 | c.1080G>A p.E360= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs1479954524; called by muse, mutect2, varscan2
- ZNF431 | c.648T>G p.L216= | Silent (SNP) | VAF 51/168 reads (30%) | called by muse, mutect2, varscan2
- ZNF786 | c.1605G>A p.R535= | Silent (SNP) | VAF 40/119 reads (34%) | catalogued as COSV100302807; called by muse, mutect2, varscan2
- ZNF80 | c.159A>G p.E53= | Silent (SNP) | VAF 7/122 reads (6%) | called by muse, mutect2
- ZNF865 | c.282G>A p.S94= | Silent (SNP) | VAF 78/319 reads (24%) | called by muse, varscan2
- AC091163.2 | n.460-412C>T | Intron (SNP) | VAF 91/248 reads (37%) | called by muse, mutect2, varscan2
- ACO1 | chr9:32384625 G>C | 5'Flank (SNP) | VAF 13/66 reads (20%) | called by muse, mutect2, varscan2
- AGA | c.*753G>T | 3'UTR (SNP) | VAF 88/391 reads (23%) | catalogued as rs1240971932; called by muse, mutect2, varscan2
- AGA | c.*752G>T | 3'UTR (SNP) | VAF 88/387 reads (23%) | called by muse, mutect2, varscan2
- ANKRD26P1 | n.36C>G | RNA (SNP) | VAF 14/75 reads (19%) | called by muse, mutect2, varscan2
- AP001042.1 | n.2441A>T | RNA (SNP) | VAF 61/166 reads (37%) | called by muse, mutect2, varscan2
- ASB18 | c.206-36C>G | Intron (SNP) | VAF 79/379 reads (21%) | called by muse, mutect2, varscan2
- C11orf96 | chr11:43943370 C>T | 3'Flank (SNP) | VAF 11/37 reads (30%) | called by muse, mutect2, varscan2
- C4A | chr6:32006042 G>A | 3'Flank (SNP) | VAF 46/483 reads (10%) | called by muse, mutect2, varscan2
- C4orf50 | c.-289G>T | 5'UTR (SNP) | VAF 87/205 reads (42%) | called by muse, mutect2, varscan2
- CADM3 | c.89-2123C>A | Intron (SNP) | VAF 27/300 reads (9%) | called by muse, mutect2
- CBFA2T3 | c.151+26264G>C | Intron (SNP) | VAF 88/651 reads (14%) | catalogued as rs1408094115; called by muse, varscan2
- CHI3L1 | c.1012-29G>A | Intron (SNP) | VAF 26/82 reads (32%) | called by muse, mutect2, varscan2
- CICP4 | chr20:64287688 C>G | 3'Flank (SNP) | VAF 50/108 reads (46%) | catalogued as rs1053497714; called by muse, mutect2, varscan2
- CPLANE1 | chr5:37169006 T>C | 3'Flank (SNP) | VAF 63/176 reads (36%) | called by muse, mutect2, varscan2
- CPNE6 | c.1113+22G>A | Intron (SNP) | VAF 39/143 reads (27%) | called by muse, mutect2, varscan2
- CRBN | c.-14G>A | 5'UTR (SNP) | VAF 51/168 reads (30%) | called by muse, mutect2, varscan2
- DCAF17 | c.*1185G>C | 3'UTR (SNP) | VAF 13/79 reads (16%) | called by muse, mutect2, varscan2
- DHRS4 | chr14:23969977 C>G | 3'Flank (SNP) | VAF 31/129 reads (24%) | called by muse, mutect2, varscan2
- DHRS4L1 | n.177-365_177-343del | Intron (DEL) | VAF 14/64 reads (22%) | called by mutect2, pindel, varscan2
- EFTUD2 | c.493-31C>G | Intron (SNP) | VAF 15/84 reads (18%) | called by muse, mutect2, varscan2
- EGLN2 | chr19:40810281 C>A | 3'Flank (SNP) | VAF 66/400 reads (17%) | called by muse, mutect2, varscan2
- ELFN1 | c.-456+5691G>T | Intron (SNP) | VAF 4/16 reads (25%) | catalogued as rs1002852993; called by muse, mutect2
- FAM20C | c.864-17751G>C | Intron (SNP) | VAF 70/356 reads (20%) | catalogued as rs929462721; called by muse, mutect2, varscan2
- FCAR | c.-24C>T | 5'UTR (SNP) | VAF 214/305 reads (70%) | catalogued as rs571488110, COSV62030744; called by muse, mutect2, varscan2
- GABRD | c.471-61C>G | Intron (SNP) | VAF 119/340 reads (35%) | called by muse, mutect2, varscan2
- GFM1 | c.689+858A>G | Intron (SNP) | VAF 27/438 reads (6%) | called by muse, mutect2
- GRIK4 | c.907-2277G>A | Intron (SNP) | VAF 12/108 reads (11%) | called by muse, mutect2, varscan2
- GUK1 | c.*16C>T | 3'UTR (SNP) | VAF 11/135 reads (8%) | catalogued as rs1224363360, COSV57158248; called by muse, mutect2
- GUSBP10 | n.73G>C | RNA (SNP) | VAF 34/128 reads (27%) | called by muse, varscan2
- HNRNPA3P1 | n.220C>T | RNA (SNP) | VAF 37/107 reads (35%) | catalogued as rs760651625; called by muse, mutect2, varscan2
- HSH2D | c.216-73G>A | Intron (SNP) | VAF 24/209 reads (11%) | called by muse, mutect2, varscan2
- IGLV8OR8-1 | n.62C>T | RNA (SNP) | VAF 10/40 reads (25%) | called by muse, mutect2, varscan2
- INTS11 | c.429+39C>T | Intron (SNP) | VAF 48/276 reads (17%) | called by muse, mutect2, varscan2
- ITSN2 | c.1723+9C>G | Intron (SNP) | VAF 6/48 reads (13%) | called by muse, mutect2, varscan2
- KCNJ11 | chr11:17388873 C>G | 5'Flank (SNP) | VAF 27/104 reads (26%) | called by muse, mutect2, varscan2
- KCNU1 | c.2010-16517T>C | Intron (SNP) | VAF 54/195 reads (28%) | called by muse, mutect2, varscan2
- KCTD8 | c.962-118189C>G | Intron (SNP) | VAF 18/149 reads (12%) | called by muse, mutect2, varscan2
- KRT6C | c.1203+18G>T | Intron (SNP) | VAF 78/474 reads (16%) | called by muse, mutect2, varscan2
- LENG8 | c.*2404_*2411del | 3'UTR (DEL) | VAF 6/51 reads (12%) | called by mutect2, pindel, varscan2
- LINC01299 | n.2201G>T | RNA (SNP) | VAF 127/568 reads (22%) | catalogued as rs1294868802; called by muse, mutect2, varscan2
- MME | c.196+24A>G | Intron (SNP) | VAF 13/101 reads (13%) | called by muse, mutect2, varscan2
- MYCBPAP | c.77-1686G>T | Intron (SNP) | VAF 12/51 reads (24%) | called by muse, mutect2, varscan2
- NEMF | c.-4C>T | 5'UTR (SNP) | VAF 51/194 reads (26%) | catalogued as COSV53595483; called by muse, mutect2, varscan2
- NF1 | c.2850+13C>G | Intron (SNP) | VAF 34/208 reads (16%) | catalogued as rs777295195; called by muse, mutect2, varscan2
- NLRP12 | c.*45G>C | 3'UTR (SNP) | VAF 193/601 reads (32%) | catalogued as COSV100145792; called by muse, mutect2, varscan2
- NLRP9 | c.2843+290G>C | Intron (SNP) | VAF 28/391 reads (7%) | called by muse, mutect2
- NOD1 | c.*1G>C | 3'UTR (SNP) | VAF 71/239 reads (30%) | called by muse, mutect2, varscan2
- NUP43 | chr6:149746537 G>C | 5'Flank (SNP) | VAF 247/460 reads (54%) | catalogued as rs781556452; called by muse, mutect2, varscan2
- ODAPH | c.*61_*80del | 3'UTR (DEL) | VAF 28/286 reads (10%) | called by mutect2, pindel
- OR4C4P | n.675G>A | RNA (SNP) | VAF 81/310 reads (26%) | catalogued as rs75667244; called by muse, mutect2, varscan2
- PLA2G7 | c.*22del | 3'UTR (DEL) | VAF 18/100 reads (18%) | catalogued as rs778182130; called by mutect2, pindel, varscan2
- PRR12 | chr19:49594705 A>G | 5'Flank (SNP) | VAF 22/116 reads (19%) | called by muse, mutect2, varscan2
- PTPRVP | n.4339G>A | RNA (SNP) | VAF 47/205 reads (23%) | catalogued as rs572519767; called by muse, mutect2, varscan2
- RBM39 | c.1175-22T>G | Intron (SNP) | VAF 15/131 reads (11%) | called by muse, mutect2, varscan2
- REXO1L1P | n.4G>C | RNA (SNP) | VAF 41/858 reads (5%) | called by muse, mutect2
- RGS3 | c.3081-98T>C | Intron (SNP) | VAF 3/8 reads (38%) | called by muse, mutect2
- RGS3 | c.3081-97G>T | Intron (SNP) | VAF 3/8 reads (38%) | called by muse, mutect2
- RGS9 | c.1407+46C>T | Intron (SNP) | VAF 49/154 reads (32%) | called by muse, mutect2, varscan2
- RN7SL495P | chr15:22611253 del C | 5'Flank (DEL) | VAF 108/854 reads (13%) | called by mutect2, pindel, varscan2
- RPL23AP42 | n.201G>A | RNA (SNP) | VAF 54/552 reads (10%) | called by muse, mutect2, varscan2
- SIGLEC14 | c.*43C>G | 3'UTR (SNP) | VAF 23/267 reads (9%) | called by muse, mutect2
- SNORD115-43 | n.28C>A | RNA (SNP) | VAF 130/522 reads (25%) | catalogued as rs185961948; called by muse, mutect2, varscan2
- SNX13 | c.-59G>C | 5'UTR (SNP) | VAF 68/230 reads (30%) | called by muse, mutect2, varscan2
- SPANXC | c.*16C>G | 3'UTR (SNP) | VAF 33/156 reads (21%) | called by muse, mutect2, varscan2
- TMEM232 | n.1012-9369C>A | Intron (SNP) | VAF 48/210 reads (23%) | catalogued as rs368521823; called by muse, mutect2, varscan2
- TNNT2 | chr1:201377627 G>C | 5'Flank (SNP) | VAF 44/367 reads (12%) | called by muse, mutect2, varscan2
- TTK | c.-2-20C>G | Intron (SNP) | VAF 30/196 reads (15%) | called by muse, mutect2, varscan2
- TUBB8P7 | n.894+282G>A | Intron (SNP) | VAF 12/94 reads (13%) | catalogued as rs1393670174; called by muse, mutect2
- TUBBP5 | n.1421G>A | RNA (SNP) | VAF 4/54 reads (7%) | catalogued as rs1217540331; called by muse, mutect2
- UBTFL2 | n.747A>T | RNA (SNP) | VAF 61/601 reads (10%) | called by muse, mutect2, varscan2
- UQCRB | c.*4175T>A | 3'UTR (SNP) | VAF 9/45 reads (20%) | called by muse, mutect2
- USP43 | c.1663-34G>T | Intron (SNP) | VAF 16/36 reads (44%) | called by muse, mutect2, varscan2
- XIAP | chrX:123860187 C>G | 5'Flank (SNP) | VAF 70/167 reads (42%) | catalogued as rs1455807743; called by muse, mutect2, varscan2
- YWHAH | c.87+5557C>A | Intron (SNP) | VAF 34/359 reads (9%) | called by muse, mutect2
